Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5711, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5711-01A (Primary Tumor).

PATIENT HISTORY:

PRE-OP DIAGNOSIS: Right renal carcinoma
POST-OP DIAGNOSIS: Same
PROCEDURE: Right laparoscopic radical nephrectomy

FINAL DIAGNOSIS:**PART 1:****RIGHT KIDNEY, RADICAL NEPHRECTOMY –**

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, FUHRMAN GRADE 3 OF 4, 7.5 cm IN GREATEST DIMENSION.
- B. CARCINOMA INVOLVES THE PERIHILAR (RENAL SINUS) ADIPOSE TISSUE.
- C. VASCULAR INVASION, IN A LARGE (MUSCLE CONTAINING) BRANCH OF THE RENAL VEIN IS PRESENT (SECTION 1H).
- D. ALL SURGICAL MARGINS ARE FREE OF NEOPLASIA.
- E. NON-NEOPLASTIC RENAL PARENCHYMA SHOWS NO SPECIFIC PATHOLOGIC ABNORMALITY.
- F. PATHOLOGIC TNM STAGING: p T3b Nx Mx.

PART 2:**ADRENAL GLAND, COMPLETION OF RADICAL NEPHRECTOMY –****ADRENAL GLAND WITH NO SPECIFIC PATHOLOGIC ABNORMALITY.****SYNOPTIC - PRIMARY Kidney/Renal Pelvis/Ureter TUMORS**

- A. Side: 1 1. Right 2. Left
- B. Location: 1
- 1. Kidney (parenchyma - cortex/medulla)
- 2. Kidney (pelvis)
- 3. Ureter
- 4. Kidney and ureter
- C. Procedure: 3
- 1. Partial nephrectomy
- 2. Simple nephrectomy
- 3. Radical nephrectomy
- 4. Ureterectomy
- 5. Other
- D. Size of neoplasm (maximum dimension; if multicentric, size of largest mass): 7.5 cm
- E. Type of malignant neoplasm: 1
- 1. Renal cell carcinoma, clear cell type (includes non-papillary granular cell RCC)
- 2. Renal cell carcinoma, chromophil cell type (papillary RCC, no clear cell component)
- 3. Renal cell carcinoma, chromophobe cell type
- 4. Renal cell carcinoma, oncocytic
- 5. Renal cell carcinoma, sarcomatoid
- 6. Collecting duct carcinoma
- 7. Urothelial carcinoma, TCCa (non-invasive)
- 8. Urothelial carcinoma, TCCa (invasive ± in-situ)
- 9. Urothelial carcinoma, squamous carcinoma
- 10. Urothelial carcinoma, adenocarcinoma
- 11. Urothelial carcinoma, small cell/neuroendocrine carcinoma
- 12. Urothelial carcinoma, mixed
- 13. Juxtaglomerular cell tumor
- 14. Wilms' tumor
- 15. Rhabdoid tumor
- 16. Clear cell sarcoma
- 17. Congenital mesoblastic nephroma
- 18. Sarcoma (non-clear cell)
- 19. Lymphoma/leukemia
- 20. Other
- F. Histologic grade
- F1. Fuhrman grade (for RCC; grades 1-4): 3
- F2. Ash grade (grade 1-4): N/A
- F3. WHO grade (grade 1-3): N/A (for TCCa)
- F4. 1998 WHO/ISUP Classification: N/A
- 1. LMP 2. LG 3. HG
- F5. Other malignant neoplasms (grades 1-3): N/A
- G. Non-neoplastic and other conditions: N/A
- 1. Glomerulopathy
- 2. Interstitial nephritis
- 3. Pyelonephritis
- 4. Nephrolithiasis
- 5. Papillary necrosis
- 6. Chronic parenchymal disease
- 7. Other
- H. Margins of resection: 2
- 1. Positive
- 2. Negative
- I. Mitotic activity: 1 per 10 high power fields
- J. Angiolymphatic invasion
- J1. Macroscopic (e.g., renal vein thrombus): 1
- J2. Microscopic: 1
- 1. Positive
- 2. Negative
- 1. Positive
- 2. Negative
- K. Number of positive lymph nodes: N/A
- L. Total number of lymph nodes examined: 0
- M. Extracapsular spread of lymph node metastases: N/A
- 1. Yes
- 2. No
- N. Adrenal gland: 1
- N1. Present 1
- N2. Involvement by renal neoplasm: 2
- N3. Other adrenal pathology: 2
- 1. Yes
- 2. No
- 1. Yes
- 2. No
- 3. Not Applicable
- 3. Not applicable
- O. TNM stage: T 3b N x M x

Source: NCI Genomic Data Commons file db6d40bb-9293-4d8d-9d0d-4b32ce88c8de (TCGA-B0-5711.8113A12D-942E-4B6E-AC19-4A608A83CD3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).